TCGA case TCGA-08-0627 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Brain; Tissue source site: UCSF.
https://portal.gdc.cancer.gov/cases/5c5945c4-c17a-43db-a012-a42aec4838e4

Biospecimens (1 sample)
- Sample TCGA-08-0627-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.3.
